Somatic mutation profile of tumor specimen PCProject_0085_T1_WES (aliquot PCProject_0085_T1_WES_1) from CMI case PCProject_0085, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.5 years (20,628 days).
Specimen PCProject_0085_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ad436bf-c040-44a0-b52c-4a7f0ab2230e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0085_SALIVA (Saliva), aliquot PCProject_0085_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e985fa4a-86a0-4746-9071-bcc84db91fa1

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 3, 5'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNNM1 | c.1067C>A p.S356* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as rs867369746; called by muse, mutect2
- MFSD6 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776105631; called by muse, mutect2, varscan2
- NLRP10 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60779140; called by muse, mutect2, varscan2
- RPS6KA4 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs772979035; called by muse, mutect2, varscan2
- HIP1 | c.3024C>G p.H1008Q | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- HRH3 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PRAMEF11 | c.1429T>A p.C477S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2
- SLC6A13 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRAF6 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GRIN2A | c.57C>T p.R19= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as rs1443213122, COSV58059234; called by muse, mutect2, varscan2
- NTSR1 | c.66G>A p.A22= | Silent (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2
- SLC12A7 | c.1197C>T p.P399= | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as rs758872605; called by muse, mutect2
- TSKU | c.832C>T p.L278= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as COSV60751769; called by muse, mutect2
- AP4S1 | c.306+3033A>G | Intron (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+1154C>G | Intron (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- COL9A1 | c.781-116G>A | Intron (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- IDH3A | c.-1G>T | 5'UTR (SNP) | VAF 23/276 reads (8%) | called by muse, mutect2
- PMS2 | c.-16A>T | 5'UTR (SNP) | VAF 52/553 reads (9%) | called by muse, mutect2
